Somatic mutation profile of tumor specimen TCGA-G9-6348-01A (aliquot TCGA-G9-6348-01A-11D-1786-08) from TCGA case TCGA-G9-6348, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.3 years (24,936 days).
Specimen TCGA-G9-6348-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e857d7cc-fcfb-4b26-bf25-083e3ab33133.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6348-10A (Blood Derived Normal), aliquot TCGA-G9-6348-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d4c4b6c-c0d0-488d-ab9a-7a847724e670

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 22, Silent 12, Splice Site 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.1317+1G>T p.X439_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV60057644; called by muse, mutect2, varscan2
- APPL2 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV51594001; called by muse, mutect2, varscan2
- CLASP2 | c.2927C>G p.A976G (on ENST00000359576; = p.A975G on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV56294625; called by muse, mutect2, varscan2
- CSH2 | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs184890744, COSV61081151; called by muse, mutect2, varscan2
- DMD | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.236); catalogued as CM159873, COSV55902813, COSV55906108; called by muse, mutect2, varscan2
- DNAH2 | c.6479A>T p.D2160V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1183187655, COSV66727694; called by muse, mutect2, varscan2
- DOCK5 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1211550897, COSV52411912; called by muse, mutect2
- DSG2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55203154; called by muse, mutect2, varscan2
- GALNTL5 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV67181239; called by muse, mutect2
- GRIK3 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs569112734, COSV66144226; called by muse, mutect2, varscan2
- HOXB3 | c.557C>A p.A186E | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV57488312; called by muse, mutect2, varscan2
- JUND | c.998A>G p.N333S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.078); catalogued as COSV53254974; called by muse, varscan2
- LRRIQ3 | c.1218G>T p.E406D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100599665, COSV63050394; called by muse, mutect2, varscan2
- MFN2 | c.708+2T>A p.X236_splice | Splice Site (SNP) | VAF 14/136 reads (10%) | catalogued as COSV52425689; called by muse, mutect2, varscan2
- MOXD1 | c.1319T>C p.I440T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV60949443; called by muse, mutect2, varscan2
- NDST4 | c.2469A>T p.K823N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52138238; called by muse, mutect2, varscan2
- PPP2R2B | c.761C>T p.A254V (on ENST00000394409; = p.A320V on NM_181674.2) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60780447; called by muse, mutect2, varscan2
- PRKCG | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV54726013; called by muse, mutect2, varscan2
- SIGLEC9 | c.946G>C p.A316P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV51588684; called by muse, mutect2
- SLC37A4 | c.43T>G p.S15A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV58156399; called by muse, mutect2, varscan2
- TLL1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1274354943, COSV50314840; called by muse, mutect2
- TUBB1 | c.375G>C p.E125D | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV53888443; called by muse, mutect2, varscan2
- ZFHX4 | c.3124C>T p.P1042S | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51497439; called by muse, mutect2, varscan2
- ZNF749 | c.2205A>C p.K735N | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.908); catalogued as COSV61948441; called by muse, mutect2, varscan2
- GALNT13 | c.645del p.G216Dfs*10 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- RFC1 | c.2684_2693+3del p.X895_splice (on ENST00000381897 / NM_001363496.2; = p.X894_splice on NM_002913.5 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 6/74 reads (8%) | called by mutect2, pindel
- ZNF333 | c.1094_1112del p.S365Lfs*43 | Frame Shift Del (DEL) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- ADAM29 | c.1182C>T p.I394= | Silent (SNP) | VAF 29/168 reads (17%) | catalogued as COSV63665768, COSV63668612; called by muse, mutect2, varscan2
- CA12 | c.615C>T p.F205= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV51608172; called by muse, mutect2
- CSH2 | c.477C>T p.R159= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as COSV100400133, COSV61081162; called by muse, mutect2, varscan2
- GAD2 | c.1347C>T p.H449= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1454799424, COSV52151713; called by muse, mutect2, varscan2
- IRX5 | c.342A>G p.P114= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV58060048; called by muse, mutect2, varscan2
- MYH4 | c.3471C>T p.A1157= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as rs956714249, COSV55116616; called by muse, mutect2, varscan2
- NRXN1 | c.186C>T p.S62= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1186547259, COSV68048908; called by muse, mutect2
- PACSIN2 | c.1404C>T p.R468= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV54317800; called by muse, mutect2, varscan2
- SCN7A | c.4329T>A p.I1443= | Silent (SNP) | VAF 31/167 reads (19%) | catalogued as COSV69274780; called by muse, mutect2, varscan2
- SLC4A1 | c.1668C>T p.N556= | Silent (SNP) | VAF 29/171 reads (17%) | catalogued as rs1346400624, COSV52263323; called by muse, mutect2, varscan2
- SV2A | c.117C>T p.D39= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as rs368036992; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNN | c.2307G>A p.P769= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as rs138969989, COSV53425861; called by muse, mutect2, varscan2
